BEATAML1.0 case 2722 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/11f0e79a-a1aa-4d68-b2c2-3e360bd5190f

Demographics
Sex at birth: female; Race: other; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Myeloid leukemia associated with Down Syndrome: ICD-O-3 morphology code: 9898/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,473 days); Progression or recurrence: no.

Biospecimens (1 sample)
- Sample BA3111D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
